CPTAC case C247230 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/17b917b5-f10d-49eb-8dcf-1f517a838d30

Demographics
Sex at birth: male; Age at index: 57 years; Vital status: Dead; Days to death: 481 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioma, NOS: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Cerebrum; Tumor grade: G4; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 481 days (1.3 years); Progression or recurrence: yes; Days to recurrence: 241 days; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: Yes.

Biospecimens (9 samples)
- Samples 1104766, 1105229, SM-JU34Q (3 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1104780, 1105243, SM-JU353 (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105280: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample C247230-TP: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Right; Preservation method: Snap Frozen.
- Sample C247230-TR1: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Right; Preservation method: Snap Frozen.
